Somatic mutation profile of tumor specimen 0DAAZA from CCDI case PBBJVU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astroblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,399 days).
Specimen 0DAAZA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 281012f5-67e0-4095-bde7-9d6372be3ca4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAAZL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83034775-fe77-4e72-a10c-469d158ed7b6

The open-access MAF lists 11 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Intron 2, RNA 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NLRP3 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.442); catalogued as rs1326407288; called by muse, mutect2, varscan2
- UTP3 | c.707A>G p.K236R | Missense Mutation (SNP) | VAF 174/444 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs1259424664; called by muse, varscan2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- ABCC8 | c.801C>T p.C267= | Silent (SNP) | VAF 123/348 reads (35%) | catalogued as rs749156441, CM092536, COSV100216993; called by muse, mutect2, varscan2
- LOXL2 | c.891C>T p.A297= | Silent (SNP) | VAF 126/355 reads (35%) | catalogued as rs774183850; called by muse, mutect2, varscan2
- MAGEC1 | c.2907C>T p.D969= | Silent (SNP) | VAF 105/282 reads (37%) | catalogued as COSV53574081; called by muse, mutect2, varscan2
- AC011525.1 | n.622G>A | RNA (SNP) | VAF 26/64 reads (41%) | catalogued as rs1426241575; called by muse, mutect2, varscan2
- ANGPTL1 | c.*13G>A | 3'UTR (SNP) | VAF 93/258 reads (36%) | catalogued as rs1485220283, COSV99328034; called by muse, mutect2, varscan2
- GLCCI1 | c.696+91A>G | Intron (SNP) | VAF 6/55 reads (11%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- UNK | c.104+91C>G | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2
